Somatic mutation profile of tumor specimen TCGA-MI-A75E-01A (aliquot TCGA-MI-A75E-01A-11D-A32G-10) from TCGA case TCGA-MI-A75E, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 61.5 years (22,457 days).
Specimen TCGA-MI-A75E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6acce52e-d712-443a-8dbc-3f08c09c0758.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MI-A75E-10A (Blood Derived Normal), aliquot TCGA-MI-A75E-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20e13cc5-7b75-4bbb-8d18-30819cbd434c

The open-access MAF lists 134 somatic variants for this specimen: 101 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 31, Frame Shift Del 7, Nonsense Mutation 5, Splice Site 1, In Frame Del 1, Intron 1, Frame Shift Ins 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886043613, CM066080, COSV53390215; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.3453A>C p.K1151N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV53961590; called by muse, mutect2, varscan2
- ADAMTS14 | c.3557G>T p.G1186V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as COSV64599375, COSV64605043; called by muse, mutect2, varscan2
- ADAMTS9 | c.1642G>C p.G548R | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.157); catalogued as COSV55774125; called by muse, mutect2, varscan2
- AHCTF1 | c.928C>T p.P310S (on ENST00000366508; = p.P284S on NM_015446.5) | Missense Mutation (SNP) | VAF 172/595 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100403413; called by muse, varscan2
- ALPP | c.1313G>A p.S438N | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs772475606, COSV67395536; called by muse, varscan2
- ANXA7 | c.694G>A p.G232S (on ENST00000372919 / NM_001320880.2; = p.G210S on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs750509037, COSV65822791; called by muse, mutect2, varscan2
- AOC1 | c.1679C>T p.S560F | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.594); catalogued as COSV62866662; called by muse, mutect2, varscan2
- APC | c.7754A>T p.K2585I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV57321329; called by muse, mutect2, varscan2
- APP | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60992998; called by muse, mutect2, varscan2
- ARHGAP35 | c.3587A>T p.Q1196L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV68328951; called by muse, mutect2, varscan2
- ATP6V1F | c.322A>T p.R108W | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50799938; called by muse, mutect2, varscan2
- CCT3 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1326859400, COSV55287260; called by muse, mutect2, varscan2
- CDH23 | c.7622A>G p.N2541S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs745345746, COSV56445895; called by muse, mutect2, varscan2
- CEP57 | c.207A>G p.I69M | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57687159; called by muse, mutect2, varscan2
- CKMT1B | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1478321371, COSV55851665; called by muse, mutect2, varscan2
- CLHC1 | c.1295T>G p.L432R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.797); catalogued as COSV68463442; called by muse, mutect2, varscan2
- CNTN5 | c.511T>C p.Y171H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99675152; called by muse, mutect2
- CTNNA2 | c.1680C>G p.N560K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as COSV58131837; called by muse, mutect2, varscan2
- CTTNBP2 | c.3535G>T p.A1179S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs1401288087, COSV50389176; called by muse, mutect2, varscan2
- DNAAF6 | c.525G>C p.L175F | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.9); catalogued as COSV60495127; called by muse, mutect2, varscan2
- ENOPH1 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as COSV56730282; called by muse, mutect2, varscan2
- FRMD4B | c.1070A>G p.Y357C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68328072; called by muse, mutect2, varscan2
- GCFC2 | c.1982A>C p.N661T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV58079113; called by muse, mutect2, varscan2
- GRM5 | c.3482T>A p.V1161E (on ENST00000305447 / NM_001143831.2; = p.V1129E on NM_000842.4) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as COSV59588213; called by muse, mutect2
- H1-2 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100642272, COSV59190930; called by muse, mutect2, varscan2
- HGFAC | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.137); catalogued as rs560293902, COSV66976519; called by muse, mutect2, varscan2
- HSH2D | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV53736856; called by muse, mutect2, varscan2
- IL12A | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59758684; called by muse, mutect2, varscan2
- JAM3 | c.377T>C p.I126T | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV54449824; called by muse, mutect2, varscan2
- KCNN1 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.033); catalogued as COSV55836729; called by muse, mutect2, varscan2
- KIAA0319L | c.1540A>G p.T514A | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs1188136112, COSV57841534; called by muse, mutect2, varscan2
- KIF26B | c.3349G>A p.E1117K | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV63636030; called by muse, mutect2, varscan2
- LAMA1 | c.8179C>T p.P2727S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as COSV67531159; called by muse, mutect2, varscan2
- LAMB1 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as rs768323491, COSV55961237; called by muse, mutect2, varscan2
- LARP1B | c.191C>G p.A64G | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV52793997; called by muse, mutect2, varscan2
- MDM1 | c.628A>G p.N210D | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs374381882; called by muse, mutect2, varscan2
- MEF2D | c.332C>G p.P111R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61726560; called by muse, mutect2, varscan2
- MUC17 | c.8971A>T p.S2991C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs1430406936, COSV60279073; called by muse, mutect2, varscan2
- MYCBP2 | c.5326G>T p.E1776* (on ENST00000357337; = p.E1814* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 14/88 reads (16%) | catalogued as COSV62008933; called by muse, mutect2, varscan2
- MYO3A | c.3215C>T p.S1072L | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV56318289, COSV99779083; called by muse, mutect2, varscan2
- NAP1L2 | c.671T>C p.I224T | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs776481839, COSV65172059; called by muse, varscan2
- NEMF | c.3035A>C p.K1012T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53586427; called by muse, mutect2, varscan2
- NIBAN2 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as rs1453484364, COSV100964853, COSV64823472; called by muse, mutect2
- NKAIN4 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV64784700; called by muse, mutect2, varscan2
- NOTCH3 | c.2734T>A p.C912S | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54625185; called by muse, mutect2, varscan2
- NOVA1 | c.385A>G p.K129E | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV57471523, COSV99947242; called by muse, mutect2, varscan2
- NRXN3 | c.253G>A p.A85T (on ENST00000557594 / NM_001272020.2; = p.A717T on NM_004796.6) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs373319691, COSV55311929; called by muse, mutect2, varscan2
- NXPE1 | c.836C>A p.S279Y (on ENST00000424269; = p.S137Y on NM_152315.5) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.6); catalogued as COSV52626640; called by muse, mutect2, varscan2
- NYNRIN | c.1595A>G p.Q532R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as COSV66840930; called by muse, mutect2, varscan2
- PABPC3 | c.1646C>A p.P549H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV55796207; called by muse, mutect2, varscan2
- PAK4 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1177227980, COSV58943520; called by muse, mutect2, varscan2
- PANX3 | c.951G>C p.K317N | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV52510956; called by muse, mutect2, varscan2
- PAX4 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58387089; called by muse, mutect2, varscan2
- PDZD2 | c.3253C>T p.P1085S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761987954, COSV56849022; called by muse, mutect2, varscan2
- PHF10 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 28/164 reads (17%) | catalogued as COSV59320867; called by muse, mutect2, varscan2
- PICK1 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs199605777, COSV63659406; called by muse, mutect2, varscan2
- PJA2 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV63271462; called by muse, mutect2, varscan2
- PKDREJ | c.512C>G p.P171R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs776386876, COSV53546182; called by mutect2, varscan2
- POTEE | c.964A>T p.S322C | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100387449; called by muse, mutect2, varscan2
- PRKDC | c.10735T>C p.S3579P | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV58041278; called by muse, mutect2, varscan2
- PRSS36 | c.2302C>G p.P768A | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.998); catalogued as COSV51635502, COSV51637092; called by muse, mutect2, varscan2
- PSEN1 | c.538A>G p.I180V | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs944088683, COSV56192907; called by muse, mutect2, varscan2
- RAB18 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1047532726, COSV63612973; called by muse, mutect2, varscan2
- RAPGEF6 | c.3483G>T p.M1161I | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); catalogued as rs1460461874, COSV57239338; called by muse, mutect2, varscan2
- RASGRF2 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.047); catalogued as rs1170821278, COSV54122139; called by muse, mutect2, varscan2
- RBP3 | c.3736C>T p.H1246Y | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs1285307142; called by muse, mutect2, varscan2
- REV3L | c.7405A>G p.I2469V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.046); catalogued as COSV62614488; called by muse, mutect2, varscan2
- RSAD2 | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV65907841; called by muse, mutect2, varscan2
- SDK1 | c.1208C>T p.T403I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.364); catalogued as COSV67354876; called by muse, mutect2, varscan2
- SHCBP1 | c.1676C>G p.A559G | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV57646211; called by muse, mutect2, varscan2
- SLC44A2 | c.382A>G p.S128G | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV59834770; called by muse, mutect2, varscan2
- SLC6A19 | c.991C>A p.Q331K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs1408934525, COSV100443899, COSV58669315; called by muse, mutect2, varscan2
- SLC9A4 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.572); catalogued as rs541859382, COSV54828553; called by muse, mutect2, varscan2
- SPINK5 | c.1330A>T p.R444W | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV56247866; called by muse, mutect2
- STXBP3 | c.1449+2T>C p.X483_splice | Splice Site (SNP) | VAF 41/315 reads (13%) | catalogued as COSV64181457; called by muse, mutect2, varscan2
- SYNE2 | c.16247T>C p.M5416T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV59938402; called by muse, mutect2, varscan2
- TBL1XR1 | c.1072G>T p.D358Y | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101467821, COSV70499453; called by muse, mutect2, varscan2
- TBX4 | c.790A>G p.S264G | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.914); catalogued as rs1212088953, COSV53604891; called by muse, mutect2, varscan2
- TEDDM1 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV62380310; called by muse, mutect2, varscan2
- TIMD4 | c.779T>A p.L260H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.083); catalogued as COSV50853903; called by muse, mutect2, varscan2
- TLR3 | c.422A>G p.N141S | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV57167263; called by muse, mutect2, varscan2
- TP53BP2 | c.2479A>T p.S827C (on ENST00000343537 / NM_001031685.3; = p.S698C on NM_005426.2) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV59065856; called by muse, mutect2, varscan2
- TRPM5 | c.2792T>A p.V931E | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV50144216; called by muse, mutect2, varscan2
- UNC79 | c.865G>T p.A289S (on ENST00000393151 / NM_001346218.2; = p.A112S on NM_020818.5) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.987); catalogued as COSV56371963; called by muse, mutect2, varscan2
- UNC79 | c.6315T>C p.D2105= (on ENST00000393151 / NM_001346218.2; = p.D1928= on NM_020818.5) | Splice Region (SNP) | VAF 16/86 reads (19%) | catalogued as COSV56371972; called by muse, mutect2, varscan2
- ZC3H12D | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV66323556, COSV66324125; called by muse, mutect2, varscan2
- ZNF385D | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV55745000; called by muse, mutect2, varscan2
- ZNF568 | c.30T>A p.N10K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.01); catalogued as COSV61740317; called by muse, mutect2, varscan2
- ZNF92 | c.529A>G p.N177D (on ENST00000328747 / NM_152626.4; = p.N108D on NM_007139.4) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV60872934; called by muse, mutect2
- ZNFX1 | c.4895A>G p.Y1632C | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65593767; called by muse, mutect2, varscan2
- AGMO | c.1165del p.A389Qfs*10 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | called by mutect2, pindel, varscan2
- CEP120 | c.1125_1128del p.T376Gfs*54 | Frame Shift Del (DEL) | VAF 26/144 reads (18%) | called by mutect2, pindel, varscan2
- DIS3L | c.1335_1354del p.M446Kfs*8 (on ENST00000319212 / NM_001143688.3; = p.M363Kfs*8 on NM_133375.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/116 reads (14%) | called by mutect2, pindel
- EVI5 | c.1081del p.Q361Rfs*2 | Frame Shift Del (DEL) | VAF 37/177 reads (21%) | called by mutect2, pindel, varscan2
- MAGI3 | c.1445_1447del p.V482_N483delinsD | In Frame Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- MRC1 | c.2146G>T p.G716* | Nonsense Mutation (SNP) | VAF 87/589 reads (15%) | called by muse, mutect2, varscan2
- MUC17 | c.13052dup p.N4352Efs*3 | Frame Shift Ins (INS) | VAF 14/110 reads (13%) | called by mutect2, pindel, varscan2
- PPP2R5A | c.618_627del p.F206Lfs*13 | Frame Shift Del (DEL) | VAF 16/140 reads (11%) | called by mutect2, pindel
- RPS6KA3 | c.365_369del p.L122* | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- SYT10 | c.128del p.G43Afs*15 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- ABCB5 | c.783C>A p.A261= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV51702476; called by muse, mutect2
- BMPR2 | c.2793G>A p.K931= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV65807339, COSV65808284; called by muse, mutect2, varscan2
- CACNA1C | c.5820G>A p.L1940= (on ENST00000399634 / NM_001167625.1; = p.L1869= on NM_000719.7) | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as COSV59694641; called by muse, mutect2, varscan2
- CCDC122 | c.420G>A p.G140= | Silent (SNP) | VAF 21/157 reads (13%) | catalogued as rs772088506, COSV55708584; called by muse, mutect2, varscan2
- CELSR3 | c.3606C>T p.V1202= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV50839486; called by muse, mutect2, varscan2
- CERKL | c.1218A>G p.A406= (on ENST00000339098 / NM_001030311.2; = p.A380= on NM_201548.5) | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV59202500; called by muse, mutect2, varscan2
- CHRNA2 | c.516C>T p.H172= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV53556141; called by muse, mutect2, varscan2
- CNBD2 | c.255T>C p.P85= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as COSV62586260; called by muse, mutect2, varscan2
- DNAH8 | c.2550T>A p.L850= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as COSV59421837; called by muse, mutect2, varscan2
- DNAJB4 | c.618A>G p.K206= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100883444; called by muse, mutect2
- DNAJB6 | c.918G>A p.K306= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV51094124; called by muse, mutect2, varscan2
- FAT3 | c.3723G>T p.V1241= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs868744035, COSV53071200; called by muse, mutect2, varscan2
- FHL2 | c.753T>C p.C251= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV59078668; called by mutect2, varscan2
- FLNB | c.1489C>T p.L497= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV55868998; called by muse, mutect2, varscan2
- GBP7 | c.1449T>A p.A483= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV54007923; called by muse, mutect2
- H1-2 | c.429C>T p.G143= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as rs762871933, COSV100642271, COSV59190923; called by muse, mutect2, varscan2
- IL10RA | c.1101C>T p.S367= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV57139590; called by muse, mutect2, varscan2
- KCNG2 | c.711C>T p.S237= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs753634460, COSV60266553, COSV60267859; called by muse, mutect2, varscan2
- LSG1 | c.1413A>G p.V471= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV54568279; called by muse, mutect2, varscan2
- NSMAF | c.399T>C p.Y133= | Silent (SNP) | VAF 52/185 reads (28%) | catalogued as rs1421782009, COSV50683545; called by muse, mutect2, varscan2
- OR2T12 | c.699G>A p.K233= | Silent (SNP) | VAF 52/328 reads (16%) | catalogued as COSV58775854; called by muse, mutect2, varscan2
- RFPL3 | c.252C>T p.V84= (on ENST00000249007 / NM_001098535.1; = p.V55= on NM_006604.2) | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as COSV50747667, COSV99966915; called by muse, mutect2, varscan2
- SACS | c.6303C>A p.S2101= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as CD1515365, COSV66533243; called by muse, mutect2, varscan2
- SEMA6D | c.1584T>G p.S528= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as COSV60371972; called by muse, mutect2, varscan2
- SHC2 | c.1116A>G p.P372= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV52743464; called by muse, mutect2, varscan2
- SHCBP1L | c.1668C>T p.T556= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV62353175; called by muse, mutect2, varscan2
- STAT2 | c.1521T>C p.Y507= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV58474077; called by muse, mutect2
- TNS4 | c.1515T>C p.N505= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV54183131; called by muse, mutect2, varscan2
- XIRP2 | c.9327G>T p.V3109= (on ENST00000628543; = p.V3284= on NM_152381.6) | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV54680095; called by muse, mutect2, varscan2
- XRCC4 | c.993C>T p.D331= (on ENST00000338635 / NM_022406.4; = p.D329= on NM_003401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/252 reads (21%) | catalogued as COSV56532270; called by muse, mutect2, varscan2
- ZNF510 | c.774A>G p.K258= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV56296091; called by muse, mutect2, varscan2
- AC244258.1 | n.311-4959C>G | Intron (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- SSPOP | n.14072A>T | RNA (SNP) | VAF 5/28 reads (18%) | catalogued as COSV65126781; called by muse, mutect2
